Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4465, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4465-01A (Primary Tumor).

■

Diagnosis:

Distal partial gastric resection with tumor-free oral resection margin and inclusion of an ulcerated poorly differentiated adenocarcinoma or gastric carcinoma of diffuse (so-called signet ring cell carcinoma), located in the prepyloric antrum in the region of the greater curvature, with infiltration of all parietal layers, encroachment on the transverse colon, several regional lymph node metastases, omentum metastases and peritoneal spread also in the region of the distal resection margin and in the region of one of the resection margins of the transverse colon resection material (■ pT4 L1 V0 R2 pN3 21/27 pM1).

Source: NCI Genomic Data Commons file 9ca01a6e-bc14-4e7c-88d6-a1c62f9c4f78 (TCGA-CG-4465.76CC9B66-F915-4038-9D9C-BC152D28CD87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).